Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9T5, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9T5-01A (Primary Tumor).

[page 1 of 5]
Collected:

Ordered by:

Location:

DIAGNOSIS:

RIGHT DISTAL URETER (AFS):

FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (BFS):

FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER, FALLOPIAN TUBES AND OVARIES (C):

BLADDER:

INTRAOPERATIVE GROSS CONSULTATION:

- TUMOR IDENTIFIED IN THE TRIGONE

FINAL DIAGNOSIS:

- INVASIVE UROTHELIAL CARCINOMA (GRADE 3-4/4) INVOLVING THE TRIGONE AND PROXIMAL URETHRA WITH EXTENSION THROUGH MUSCULARIS PROPRIA AND INTO THE SUPERFICIAL PERIVASCULAR SOFT TISSUE, BUT NOT AT THE INKED MARGINS
- UROTHELIAL CARCINOMA IN SITU (FLAT LESION)
- INKED RADIAL AND DISTAL URETHRA/VAGINAL CUFF RESECTION MARGINS, FREE OF UROTHELIAL MALIGNANCY

PERIVESICAL LYMPH NODE:

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF 11 LYMPH NODES EXAMINED (1/11)

BILATERAL OVARIES AND FALLOPIAN TUBES:

- BENIGN INACTIVE OVARIES WITH PHYSIOLOGICAL CHANGES AND BENIGN INCLUSION CYSTS
- BENIGN FALLOPIAN TUBES WITH BENIGN PARATUBAL CYSTS
- NO MALIGNANCY IDENTIFIED

VAGINAL CUFF MUCOSA:

- BENIGN SQUAMOUS MUCOSA AND STROMA
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PARA AORTIC LYMPH NODES (D):

- NO METASTATIC CARCINOMA IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LEFT COMMON ILIAC LYMPH NODES (E):

- NO METASTATIC CARCINOMA IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

RIGHT PARA CAVAL LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT COMMON ILIAC LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

RIGHT LYMPH NODE OF CLOQUET (H):

- BENIGN FIBROFATTY TISSUE
- NO LYMPHOID TISSUE IDENTIFIED

RIGHT EXTERNAL ILIAC LYMPH NODES (I):

- NO METASTATIC CARCINOMA IDENTIFIED IN 17 LYMPH NODES EXAMINED (0/17)

ICD-O-3

Carcinoma, urothelial NOS
C67.8 8120/3

Site Bladder NOS C67.9

Overlapping lesion of bladder
C67.8

JW 3/26/14

[page 2 of 5]
Collected:

Ordered by:

Location:

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN 22 LYMPH NODES EXAMINED (0/22)

LEFT LYMPH NODE OF CLOQUET (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT EXTERNAL ILIAC LYMPH NODES (L):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN 22 LYMPH NODES EXAMINED (0/22)

VAGINAL WALL ABSCESS (N):

- BENIGN SQUAMOUS MUCOSA AND STROMA
- NO INFECTIONS, DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PRE-SCIATIC LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT PRE-SCIATIC LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT PROXIMAL URETER (Q):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

TOTAL LYMPH NODES:

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF 112 LYMPH NODES EXAMINED (1/112)

PATHOLOGIC TNM STAGE: pT3aN1MX

SPECIMEN SOURCE:

AFS: "Right distal ureter-f/s"

BFS: "Left distal ureter-f/s"

C: "Bladder, fallopian tubes and ovaries"

D: "Left para aortic LN"

E: "Left common iliac LN"

F: "Right para caval LN"

G: "Right common iliac L. nodes"

H: "Right LN of Cloquet"

I: "Right external iliac LN"

J: "Right obturator hypogastric LN"

K: "Left LN of Cloquet"

L: "Left external iliac LN"

M: "Left obturator hypogastric LN"

N: "Vaginal wall abscess"

O: "Right pre-sciatic LN"

P: "Left pre-sciatic LN"

Q: "Right prox ureter"

[page 3 of 5]
Collected:

Ordered by:

Location:

R: "Left prox ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter-f/s". It consists of a short segment of ureter which is 0.4 cm in length and 0.3 cm in diameter. Entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter-f/s". It consists of a short segment of ureter which is 0.3 cm in length and 0.3 cm in diameter. Entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Bladder, fallopian tubes and ovaries". It consists of a bladder with attached bilateral tubes and ovaries. Overall, the specimen measures 23 x 15 x 5 cm with a smooth, glistening, mobile peritoneum which is 18 x 12 by less than 0.1 cm. The bladder itself measures 7 x 7 x 3 cm. There is a soft pink vaginal cuff at the distal aspect of the bladder urethra which is 2 x 2 x 2 cm. The specimen is inked black around the outer surface and the specimen is opened along the anterior aspect to reveal a large ulcerated tumor 5 x 2.5 cm in the trigone area and focally in the proximal urethra. The urethra itself is 3.5 cm long by 1.5 cm in circumference and appears unremarkable. The rest of the bladder mucosa appears to be unremarkable. The bladder wall around the tumor is thickened 2.0 cm in thickness and the uninvolved wall is 0.5 cm in thickness. Both attached ureters are opened longitudinally to reveal unremarkable mucosa with the right ureter 6.5 cm long by 0.6 cm in circumference and the left ureter 5.5 cm long by 0.6 cm in circumference. The specimen is taken back to the O.R. to show the surgical staff in aid to the patient care. The tumor is then serially sectioned to reveal gross invasion through the muscularis wall but not into perivesical fat grossly. Representative sections of the tumor are submitted from C1 to C13. Representative sections of the normal bladder mucosa are submitted in cassettes C14 through C18. The perivesical fat is examined for lymph nodes and a few possible lymph nodes are identified and submitted in cassettes C19 and C20. Bilateral tubes and ovaries are examined. The right ovary is 2.5 x 1.5 x 1 cm and the left ovary is 2 x 1.5 x 0.7 cm. The right fallopian tube is soft pink tubular structure 2.5 cm in length by 0.6 cm in diameter, and the left fallopian tube is 3 cm long and 0.5 cm in diameter. Representative sections are submitted in cassettes C21 through C23.

D: The specimen is received in formalin and labeled "Left para aortic LN". It consists of one piece of soft yellow fatty tissue measuring 3 x 2 x 1 cm. No obvious lymph nodes are identified. Entirely submitted in one cassette.

E: The specimen is received in formalin and labeled "Left common iliac LN". It consists of multiple small pieces of soft yellow fatty tissue measuring in aggregate 3.6 x 3.5 x 0.8 cm. No obvious lymph nodes are identified. Entirely submitted in one cassette.

F: The specimen is received in formalin and labeled "Right para caval LN". It consists of two pieces of soft yellow fatty tissue measuring in aggregate 4 x 2.5 x 0.5 cm. No obvious lymph nodes are identified. Entirely submitted in one cassette.

G: The specimen is received in formalin and labeled "Right common iliac L. nodes". It consists of three pieces of soft yellow fatty tissue measuring in aggregate 5 x 4 x 1.5 cm. No obvious lymph nodes are identified. Entirely submitted in three cassettes.

[page 4 of 5]
Collected		
Ordered by		Location

H: The specimen is received in formalin and labeled "Right LN of Cloquet". It consists of one small piece of soft yellow fatty tissue measuring 1.6 x 1.4 x 1 cm. No obvious lymph nodes are identified. Entirely submitted in one cassette.

I: The specimen is received in formalin and labeled "Right external iliac LN". It consists of multiple pieces of soft yellow fatty tissue not measured. No obvious lymph nodes are identified. Entirely submitted in four cassettes.

J: The specimen is received in formalin and labeled "Right obturator hypogastric LN". It consists of multiple pieces of soft yellow fatty tissue measuring in aggregate 7 x 6 x 2 cm. No obvious lymph nodes are identified. Entirely submitted in five cassettes.

K: The specimen is received in formalin and labeled "Left LN of Cloquet". It consists of one piece of soft yellow fatty tissue measuring 2.6 x 1.6 x 1 cm. No obvious lymph nodes are identified. Entirely submitted in one cassette.

L: The specimen is received in formalin and labeled "Left external iliac LN". It consists of three pieces of soft yellow fatty tissue measuring in aggregate 4 x 2 x 1 cm. No obvious lymph nodes are identified. Entirely submitted in two cassettes.

M: The specimen is received in formalin and labeled "Left obturator hypogastric LN". It consists of multiple pieces of soft yellow fatty tissue measuring in aggregate 6 x 5 x 2 cm. No obvious lymph nodes are identified. Entirely submitted in five cassettes.

N: The specimen is received in formalin and labeled "Vaginal wall abscess". It consists of a small strip-like fragment of soft pink mucosa-like tissue which is 1.4 x 0.5 x 0.5 cm. Entirely submitted in one cassette.

O: The specimen is received in formalin and labeled "Right pre-sciatic LN". It consists of a small piece of soft yellow fatty tissue measuring 2.5 x 1.5 x 0.8 cm. No obvious lymph nodes are identified. Entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Left pre-sciatic LN". It consists of a small piece of soft yellow fatty tissue measuring 2 x 1.5 x 0.6 cm. No obvious lymph nodes are identified. Entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Right prox ureter". It consists of a stapled segment of ureter which is 0.6 cm in length by 0.3 cm in diameter. The specimen is serially sectioned and entirely submitted in one cassette.

R: The specimen is received in formalin and labeled "Left prox ureter". It consists of a stapled segment of ureter with attached fat which is 0.9 cm long by 0.3 cm in diameter. The specimen is serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS:	frozen section, right distal ureter
BFS:	frozen section, left distal ureter
C1:	vaginal cuff margins
C2:	right ureter margin
C3:	left ureter margin
C4-10:	tumor with inked radial margin
C11:	right ureterovesical junction
C12:	left ureterovesical junction
C13:	anterior wall
C14:	right lateral wall

[page 5 of 5]
Collected
Ordered by

Location

C15: right posterior wall
C16: dome
C17: left posterior wall
C18: left lateral wall
C19: right perivesical lymph nodes, bisected (two)
C20: left perivesical fat
C21: right ovary and tube
C22: left ovary and tube
C23: left paratubal cyst
D: left para-aortic lymph node - all embedded
E: left common iliac lymph node - all embedded
F: right paracaval lymph node - all embedded
G1-3: right common iliac lymph nodes - all embedded
H: right lymph node of Cloquet - all embedded
I1-4: right external iliac lymph node - all embedded
J1-5: right obturator hypogastric lymph node - all embedded
K: left lymph node of Cloquet - all embedded
L1,2: left external iliac lymph node - all embedded
M1-5: left obturator hypogastric lymph node - all embedded
N: vaginal wall abscess - all embedded
O: right presciatic lymph node - all embedded
P: left presciatic lymph node - all embedded
Q: right proximal ureter - all embedded
R: left proximal ureter - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- benign

BFS: Left distal ureter:
- benign

INTRAOPERATIVE GROSS CONSULTATION

Bladder:
- tumor identified in the trigone

MICROSCOPIC EXAMINATION:

A-R: See final microscopic diagnosis.

Source: NCI Genomic Data Commons file 93ddd684-701e-460e-968c-a49699dfd490 (TCGA-XF-A9T5.23A2FC99-03F3-4A72-8F33-14ED56125E65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).